Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6342, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6342-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. PROSTATE

TCGA - G9 - 6342

SPECIMEN(S):

A. PROSTATE

GROSS DESCRIPTION:

A. PROSTATE

Received fresh labeled with the matching patient identifiers is a resected prostate gland weighing 37 g and measuring 5-cm from right to left, 4.1-cm from apex to base and 3.4-cm from anterior to posterior. The external capsule is smooth, red and intact. The specimen is inked as follows: Apex-red, anterior-orange, posterior-black, base -blue, right-green, left-yellow. The apex and base are removed to yield a new weight of 21-g. The specimen is serially sectioned from apex to base. Cut section shows firm tan fibrous parenchyma showing no obvious lesions or nodules. The right and left seminal vesicle measure 1.6 x 1.2 x 0.6 and 2.3 x 1 x 0.6 cm respectively. Both are bisected to show beige tan cystic tissue. The right and left vas measure 2.5 x 0.4 , and 3.5 x 0.4 cm respectively. Both are serially sectioned to show firm tan tube structure. A portion of the specimen is submitted for tissue procurement. The remainder is entirely submitted for microscopic evaluation. Cassettes are submitted as follows:

- A1: Right apex
- A2: Left Apex
- A3: Level 1 right side
- A4: Level 1 left side
- A5: Level 2 capsule right side
- A6: Level 2 capsule left side
- A7: Level 3 capsule right side
- A8: Level 3 capsule left side
- A9: Level 4 right anterior
- A10: Level 4 right posterior
- A11: Level 4 left anterior
- A12: Level 4 left posterior
- A13: Right lateral base
- A14: Right base
- A15: Right base with proximal urethral margin
- A16: Left base with proximal urethral margin
- A17: Left base
- A18: Left lateral base
- A19: Right seminal vesicle and right vas
- A20: Left seminal vesicle and left vas

DIAGNOSIS:

A. PROSTATE, PROSTATECTOMY:

-ADENOCARCINOMA, GLEASON GRADE 3+3 (6/10) WITH A MINOR TERTIARY COMPONENT OF GRADE 4 (<5%) INVOLVING AN ESTIMATED 20% OF THE RIGHT AND LEFT LOBES WITH FOCAL EXTRAPROSTATIC EXTENSION (SEE SYNOPTIC REPORT).

- RIGHT AND LEFT SEMINAL VESICLES NEAGTIVE FOR CARCINOMA.

NOTE: The foci of extraprostatic extension and overall grade were reviewed with Dr. who agrees with these findings.

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: PROSTATE

Location: Left

Right

Posterior lateral

Apical

Basal

WHO CLASSIFICATION

Epithelial tumors

[page 2 of 2]
Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 20%

Gleason Grade/Sum:: Grade 3 + 3 , Sum 6 /10; Tertiary grade 4

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: Yes

Details: focal base and inferior left lateral

Bladder Neck Involved: No

Margins Involvement: No

Frozen Performed: No

Lymph Nodes: No lymph nodes sampled

Other Pathologic Findings: None identified

Pathological Staging (pTNM): T 3a N X M X

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

Source: NCI Genomic Data Commons file 6523fc5a-8f62-4926-9319-00696a7abad8 (TCGA-G9-6342.80379CB8-9FB7-4E01-9E4A-2BF7813DC839.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).